Gene-level copy-number profile of tumor specimen TCGA-L5-A4OT-01A from TCGA case TCGA-L5-A4OT, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 77.1 years (28,162 days).
Specimen TCGA-L5-A4OT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.6ced3607-4b89-4c2e-a18f-4385e95fe272.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OT-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6633aec9-e35f-43fb-a3ad-19eea8ac2f1f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 12; copy number 2: 9,799; copy number 3: 11,657; copy number 4: 27,443; copy number 5: 2,922; copy number 6: 3,619; copy number 7: 3,561; copy number 9: 383; copy number 10: 6; copy number 11: 36; copy number 15: 15; copy number 17: 13; copy number 20: 26; copy number 21: 1; copy number 25: 17; copy number 27: 8; copy number 28: 60; copy number 29: 9; copy number 33: 39; copy number 36: 81; copy number 37: 10; copy number 47: 7; copy number 52: 72.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OT-01A-11D-A28A-01): tumor purity 0.47, ploidy 3.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:231,767,464–231,945,233, 3 genes (within-gene range 0–6): AL136171.2, AL136171.1, DISC1-IT1.
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.
- chr16:78,872,739–79,017,429, 6 genes: AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4.
- chr18:50,560,087–51,085,045, 11 genes (within-gene range 0–2): MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 783 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:39,571,478–41,968,366, 35 genes, copy number 10–37: CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6.
- chr5:42,799,880–45,895,970, 56 genes, copy number 11–33: SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr7:95,297,676–106,770,207, 319 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr7:110,662,644–115,833,373, 52 genes, copy number 9: IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1, DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1, ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30, AC073137.1, AC073348.1, AC073348.2, PPP1R3A, FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA.
- chr7:120,005,976–120,750,337, 4 genes, copy number 10 (within-gene range 4–10): RNU1-29P, AC004946.1, AC004946.2, KCND2.
- chr8:8,895,813–18,371,484, 220 genes, copy number 28–52 (broad region; genes not listed).
- chr12:20,361,732–25,409,445, 74 genes, copy number 11–25 (within-gene range 5–25) (broad region; genes not listed).
- chr12:25,423,600–25,436,238, 2 genes, copy number 25: AC092451.2, FAM133GP.
- chr12:28,978,584–29,381,189, 9 genes, copy number 29: AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2.
- chr12:33,923,374–34,249,958, 12 genes, copy number 9: RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
